CCDI case PBCFKX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/164b5f38-0573-4c96-b026-2d80c198f13c

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.2 years (3,719 days).

Biospecimens (3 samples)
- Sample 0DQZ3D: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQZ4B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DQZ4N: Tissue type: Tumor; Specimen type: Solid Tissue.
